Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MU, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MU-01A (Primary Tumor).

[page 1 of 2]
Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex: (Age: F
Location/Client:

Surgical Pathology Report

Final Diagnosis

ADRENAL GLAND, RIGHT, ADRENALECTOMY:
- PHEOCHROMOCYTOMA.

SIZE OF TUMOR: 4 x 1.8 x 1.5 cm.

WEIGHT OF TUMOR: 21 gm.

EXTENT OF TUMOR: Tumor is confined to the adrenal gland with minimal capsular invasion.

- MARGINS OF RESECTION:
- MARGINS ARE FREE OF TUMOR.

- BLOOD VESSEL INVASION:
- NOT IDENTIFIED.

- LYMPH VESSEL INVASION:
- NOT IDENTIFIED.

MITOTIC ACTIVITY: 15-18/20 HIGH POWER FIELD.

NUCLEAR ATYPIA: MODERATE.

NECROSIS: ABSENT.

- ADDITIONAL FINDINGS AND COMMENTS:

- THE TUMOR SHOWS A DIFFUSE PATTERN OF GROWTH, HIGH CELLULARITY WITH CELLULAR MONOTONY. THE PASS SCORE IS 6, THEREFORE IT CANNOT BE CHARACTERIZED EQUIVOCALLY AS A BENIGN LESION UTILIZING THIS CLASSIFICATION.
- L. Thompson, American J Surgical Pathology, 2002, 26 (5): 551-566.

- ANCILLARY STUDIES:

- IMMUNOHISTOCHEMICAL STUDIES ARE PERFORMED, THE RESULTS ARE AS FOLLOWS:
- ACTH (A7): NON-CONTRIBUTORY.
- SYNAPTOPHYSIN (A9): MODERATELY POSITIVE CYTOPLASMIC STAINING.
- CHROMOGRANIN (A7): STRONGLY POSITIVE CYTOPLASMIC GRANULAR STAINING.
- EMA (A7): NEGATIVE IN TUMOR, POSITIVE IN CORTICAL EPITHELIAL CELLS.

pTN STAGE: pT1.

REGIONAL LYMPH NODES: CANNOT BE ASSESSED.

DISTANT METASTASIS: pMX.

[page 2 of 2]
This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

RIGHT ADRENAL GLAND:

- POSITIVE FOR NEOPLASIA.

Clinical History

Pheochromocytoma of right adrenal gland

Pre-Operative Diagnosis

(Not Provided)

Post-Operative Diagnosis

(Not Provided)

Gross Description

A. RIGHT ADRENAL GLAND (FRESH): The specimen, labeled with the patient's name and accession number, is an adrenal gland (2 x 0.5 cm). Weighing 21 grams, which has a tan yellow cortex (0.1 cm in thickness) and hemorrhagic medulla (0.3 cm in thickness). There is an attached to the adrenal a cystic lesion (4 x 1.8 x 1.5 cm) with smooth, tan gray external surface, which is inked black. Opening reveals tan brown irregular internal surface with multiple papillary friable projections, filling the lumen of the cyst. One fragment of the mass was frozen for intraoperative diagnosis and possible further examination. Three touch preps were made. The specimen is submitted entirely in cassettes A1-11.

Immunohistochemical staining performed in this case may involve reagents labeled as anatomic specific reagents. For these cases: This test was developed and its performance characteristics determined by Department of Pathology. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Source: NCI Genomic Data Commons file 9fbc92f1-5771-4e75-96b4-8b01ce3c0b7c (TCGA-SR-A6MU.5C497DAE-44D4-4C6C-86A3-D9A0D4986F61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).